Somatic mutation profile of tumor specimen TCGA-XY-A9T9-01A (aliquot TCGA-XY-A9T9-01A-11D-A435-10) from TCGA case TCGA-XY-A9T9, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 37.2 years (13,604 days).
Specimen TCGA-XY-A9T9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98db0614-6d6d-43c5-bcdb-becbcc7c4c06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XY-A9T9-10A (Blood Derived Normal), aliquot TCGA-XY-A9T9-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e42e58a-3fcb-40c7-b4bd-e4bb03162f5c

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 17/93 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- C1orf68 | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.225); catalogued as rs1484060849; called by muse, mutect2, varscan2
- MCF2L2 | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); catalogued as COSV100191073, COSV61052328; called by muse, mutect2, varscan2
- ATRIP | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GABRG1 | c.1009G>C p.V337L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNX19 | c.2954C>G p.S985C | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- ZNF440 | c.1338_1341del p.Q446Hfs*3 | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | called by mutect2, pindel, varscan2
- ZNF646 | c.862C>T p.H288Y | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CIZ1 | c.984G>A p.P328= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs145714867; called by muse, mutect2, varscan2
- LTK | c.306C>T p.A102= | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- PRKDC | c.7977G>C p.L2659= | Silent (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
